Gene-level copy-number profile of tumor specimen TCGA-AN-A03X-01A from TCGA case TCGA-AN-A03X, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 74.4 years (27,163 days).
Specimen TCGA-AN-A03X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.eb8bc681-2b7a-4100-a3cc-b8b90e1f017f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AN-A03X-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/71db2ca5-c6e7-416b-8fb1-0d9e44f48e59

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 10,187; copy number 2: 38,939; copy number 3: 7,214; copy number 4: 3,355; copy number 5: 19; copy number 6: 16; copy number 7: 33; copy number 9: 54.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AN-A03X-01A-21D-A011-01): tumor purity 0.56, ploidy 1.95, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 122 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:59,669,312–59,810,778, 10 genes, copy number 5–7: AP000640.2, RN7SKP192, OR10V1, STX3, OR10Y1P, OR10V3P, OR10V2P, AP000640.1, FABP5P7, MRPL16.
- chr11:61,873,519–61,967,634, 6 genes, copy number 6: FADS3, MIR6746, RAB3IL1, RNU6-1243P, BEST1, FTH1.
- chr11:68,980,021–69,819,416, 26 genes, copy number 7: MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3.
- chr11:76,860,867–80,327,911, 57 genes, copy number 5–9: ACER3, AP002498.1, B3GNT6, CAPN5, OMP, MYO7A, GDPD4, TOMM20P1, PAK1, AP003680.1, CLNS1A, RNU7-59P, AQP11, RSF1, Y_RNA, RSF1-IT2, FTH1P16, RSF1-IT1, AP000580.1, AAMDC, AP002812.2, AP002812.3, AP002812.5, AP002812.1, INTS4, AP002812.4, AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2, ALG8, RNU6-126P, KCTD21-AS1, KCTD21, USP35, GAB2, AP002985.1, AP003086.1, AP003086.3, AP003086.2, LINC02728, NARS2, AP003110.1, RNU6-311P, COPS8P3, TENM4, AP002768.1, AP002957.1, AP001547.1, MIR708, MIR5579, AP001978.1, AP001541.1, AP001284.1, AP006295.1.
- chr11:92,161,106–92,931,322, 9 genes, copy number 5: RPL7AP57, NDUFB11P1, FAT3, PGAM1P9, AP000722.1, RPS3AP42, AP003718.1, LINC02746, AP003171.2.
- chr11:99,020,949–100,358,885, 1 gene, copy number 6 (within-gene range 4–6): CNTN5.
- chr11:100,336,856–101,209,591, 9 genes, copy number 6: RPA2P3, RN7SL222P, PPIAP43, ARHGAP42-AS1, ARHGAP42, RN7SKP115, PGR, PGR-AS1, AP001533.1.
- chr16:25,236,001–25,454,647, 4 genes, copy number 5 (within-gene range 3–5): ZKSCAN2, ZKSCAN2-DT, LINC02191, CYCSP39.

Autosomal genes at a single copy (total copy number 1): 10,187. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
